Somatic mutation profile of tumor specimen TCGA-AG-3892-01A (aliquot TCGA-AG-3892-01A-01D-1989-10) from TCGA case TCGA-AG-3892, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 57.2 years (20,880 days).
Specimen TCGA-AG-3892-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef7e3f3e-3eb0-4d64-98be-1a282a02130e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3892-10A (Blood Derived Normal), aliquot TCGA-AG-3892-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9815f617-cf2b-4ea1-b460-9c80eefa4b42

The open-access MAF lists 2,802 somatic variants for this specimen: 2,301 protein-altering or splice-affecting, 438 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,921, Silent 438, Nonsense Mutation 319, Splice Site 26, RNA 23, Intron 20, Frame Shift Del 15, Splice Region 11, 3'UTR 10, 5'UTR 5, Frame Shift Ins 4, Nonstop Mutation 4.

Variants (750 of 2,802; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 124/226 reads (55%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as rs971882211, CM141595, COSV55735390; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | catalogued as rs1393544920, COSV100483393, COSV58591239; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CYBB | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 31/173 reads (18%) | catalogued as rs886041192, CM960436, COSV66085069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHDDS | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.019); catalogued as rs1229969030, COSV52575269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 16/187 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2
- FBXW7 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 45/207 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs200698994; called by muse, mutect2, varscan2
- FGFR2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 17/115 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747502397, COSV60645207, COSV60646793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 25/143 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OTX2 | c.265C>T p.R89* (on ENST00000408990 / NM_172337.3; = p.R97* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 28/113 reads (25%) | catalogued as rs104894464, CM051593, CM104945, COSV59766659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 102/279 reads (37%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RFX6 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445567359, COSV60586495, COSV60587831; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 134/820 reads (16%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- STXBP1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs786205598, CM162486, COSV64812245; ClinVar: uncertain significance / pathogenic / not provided; called by mutect2, varscan2
- TMEM126A | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 39/427 reads (9%) | catalogued as rs121434508, CM092006, COSV58735100; ClinVar: pathogenic; called by muse, mutect2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 55/295 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs570351376, COSV52628354; called by muse, mutect2, varscan2
- AASDHPPT | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV53789463; called by muse, mutect2, varscan2
- ABCA10 | c.2206C>A p.L736I | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV52221612; called by muse, mutect2, varscan2
- ABCA12 | c.2285T>G p.L762* (on ENST00000272895 / NM_173076.3; = p.L444* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 45/245 reads (18%) | catalogued as CM153356, COSV55964590; called by muse, mutect2, varscan2
- ABCA12 | c.1211G>A p.R404Q (on ENST00000272895 / NM_173076.3; = p.R86Q on NM_015657.3) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752328328, COSV55961290, COSV99789386; called by muse, mutect2, varscan2
- ABCA13 | c.5881A>C p.N1961H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV70027176; called by muse, mutect2, varscan2
- ABCA4 | c.4801G>T p.E1601* | Nonsense Mutation (SNP) | VAF 22/297 reads (7%) | catalogued as COSV64670775; called by muse, mutect2
- ABCA9 | c.3800G>A p.R1267K | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV60626993; called by muse, varscan2
- ABCB1 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55954869; called by muse, mutect2, varscan2
- ABCB4 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55937335; called by muse, mutect2, varscan2
- ABCC11 | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV62324111; called by muse, mutect2, varscan2
- ABCC2 | c.3053C>A p.S1018Y | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV64986928; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 22/140 reads (16%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC8 | c.3540C>A p.Y1180* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV56852727; called by muse, mutect2, varscan2
- ABCG2 | c.1527G>T p.M509I | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV52947037; called by muse, mutect2, varscan2
- ABCG2 | c.1356G>T p.K452N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV52947046; called by muse, mutect2, varscan2
- ABHD10 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV56325747; called by muse, mutect2
- ABI3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs200803220, COSV56799265; called by muse, mutect2, varscan2
- ABR | c.815G>A p.R272H (on ENST00000302538 / NM_021962.5; = p.R235H on NM_001092.5) | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779655290, COSV52152236; called by muse, mutect2
- AC006059.2 | c.874A>C p.I292L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV59607884; called by muse, mutect2, varscan2
- AC098582.1 | c.2111T>C p.V704A | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52021686; called by muse, mutect2, varscan2
- AC134980.2 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754080672, COSV100171525; called by muse, varscan2
- ACAD9 | c.668T>G p.F223C | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100459022; called by muse, mutect2, varscan2
- ACADM | c.143T>G p.F48C | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63720642; called by muse, mutect2, varscan2
- ACBD6 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs777457819, COSV62571410, COSV62574403; called by muse, mutect2, varscan2
- ACCSL | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV66581644; called by mutect2, varscan2
- ACKR2 | c.750A>C p.K250N | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as COSV56178490; called by muse, mutect2, varscan2
- ACOT9 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV60538191; called by muse, mutect2, varscan2
- ACOX3 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); catalogued as COSV62712554, COSV62713252; called by muse, varscan2
- ACR | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV53361322; called by muse, mutect2, varscan2
- ACSBG2 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV53125808; called by muse, mutect2, varscan2
- ACSL3 | c.658A>C p.K220Q | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100657893; called by muse, mutect2, varscan2
- ACVR2B | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100754186; called by muse, mutect2
- ACYP1 | c.39A>C p.E13D | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53135311; called by muse, mutect2, varscan2
- ADAD1 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | catalogued as COSV56643345, COSV56644581; called by muse, mutect2, varscan2
- ADAM21 | c.484A>C p.N162H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV50797475; called by muse, mutect2, varscan2
- ADAM23 | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV100007065; called by muse, mutect2, varscan2
- ADAMTS12 | c.4160G>A p.R1387H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745489312, COSV61254566, COSV61256573, COSV61285243; called by muse, mutect2, varscan2
- ADAMTS18 | c.2802-1G>T p.X934_splice | Splice Site (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99271690; called by muse, mutect2, varscan2
- ADAMTS18 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs746386082, COSV51417926; called by muse, mutect2, varscan2
- ADAMTS18 | c.1523A>C p.D508A | Missense Mutation (SNP) | VAF 79/412 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV51417931; called by muse, mutect2, varscan2
- ADAMTS3 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.143); catalogued as rs1444087701, COSV54394986; called by muse, varscan2
- ADAMTS5 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.835); catalogued as rs546124249, COSV53175804; called by muse, mutect2, varscan2
- ADAMTS9 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs766944266, COSV55777384; called by muse, varscan2
- ADAMTSL2 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100618940; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs751167134, COSV54439652; called by muse, mutect2, varscan2
- ADCK1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372281167, COSV53082469; called by muse, mutect2, varscan2
- ADCY10 | c.3111C>A p.F1037L | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63238491; called by muse, mutect2, varscan2
- ADCY10 | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV63241920; called by muse, mutect2, varscan2
- ADCY2 | c.211-2A>C p.X71_splice | Splice Site (SNP) | VAF 64/338 reads (19%) | catalogued as COSV100602176; called by muse, mutect2, varscan2
- ADGRF1 | c.572G>T p.R191I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.403); catalogued as rs753292636, COSV51944555, COSV51946042; called by mutect2, varscan2
- ADGRG4 | c.2642C>A p.S881Y | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV54960054; called by muse, mutect2, varscan2
- ADGRG4 | c.3941C>T p.S1314L | Missense Mutation (SNP) | VAF 90/328 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs751562884, COSV54950446; called by muse, mutect2, varscan2
- ADGRG4 | c.7887C>A p.F2629L | Missense Mutation (SNP) | VAF 29/511 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1334865153, COSV99794222; called by muse, mutect2
- ADGRL3 | c.1433C>A p.S478Y (on ENST00000506720 / NM_001322402.2; = p.S410Y on NM_015236.6) | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV72267671, COSV72269295; called by muse, mutect2, varscan2
- ADGRV1 | c.2483T>C p.V828A | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs757135353, COSV67988569; called by muse, mutect2, varscan2
- ADGRV1 | c.16639C>T p.R5547C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs1446694263, COSV67987576; called by muse, mutect2, varscan2
- ADH1B | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 59/340 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV59297101; called by muse, mutect2, varscan2
- ADH6 | c.1023G>T p.L341F | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52956749; called by muse, mutect2, varscan2
- ADNP2 | c.753T>G p.I251M | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51540059; called by muse, mutect2, varscan2
- ADRB2 | c.289A>C p.K97Q | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs894015862; called by muse, mutect2
- AFF1 | c.3092C>A p.S1031* | Nonsense Mutation (SNP) | VAF 64/371 reads (17%) | catalogued as COSV57121220; called by muse, mutect2, varscan2
- AFF2 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782465333, CM128723, COSV53995030; called by muse, mutect2, varscan2
- AFF2 | c.3805G>T p.E1269* | Nonsense Mutation (SNP) | VAF 18/302 reads (6%) | catalogued as COSV54008651, COSV99662654; called by muse, mutect2
- AFTPH | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV53218714, COSV53219240; called by muse, mutect2, varscan2
- AGBL5 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs745474264, COSV59936998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMAT | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs1283769265, COSV65435978; called by muse, mutect2, varscan2
- AGPAT5 | c.885T>G p.F295L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV53447755; called by muse, mutect2, varscan2
- AGTR1 | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.391); catalogued as COSV104421906; called by muse, mutect2
- AGTR2 | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 81/362 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64156183; called by muse, mutect2, varscan2
- AHNAK | c.6435T>G p.D2145E | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99946304; called by muse, mutect2, varscan2
- AICDA | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs1489687161, CM064963, COSV57564138; called by muse, mutect2, varscan2
- AIFM1 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV54855748; called by muse, mutect2
- AKAP3 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as rs1467971895, COSV57413779; called by muse, mutect2, varscan2
- AKAP4 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV62074797; called by muse, mutect2, varscan2
- AKAP9 | c.254G>T p.R85I | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62350086; called by muse, mutect2, varscan2
- AKAP9 | c.10516C>A p.L3506I (on ENST00000359028; = p.L3482I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV62350106; called by muse, mutect2, varscan2
- AKIRIN2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 30/423 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57636871; called by muse, mutect2
- AKR1C2 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 34/215 reads (16%) | catalogued as COSV66333502, COSV66334408; called by muse, mutect2, varscan2
- AKR1C4 | c.958T>G p.S320A | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54123939; called by muse, mutect2, varscan2
- AL136295.1 | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV55780584; called by muse, mutect2, varscan2
- AL163195.3 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.398); catalogued as COSV100250465; called by muse, mutect2, varscan2
- ALB | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs774294755, COSV55738750, COSV55739357; called by mutect2, varscan2
- ALB | c.1782G>T p.E594D | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV55739365; called by muse, mutect2, varscan2
- ALG14 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs767402341, COSV64635180; called by muse, mutect2, varscan2
- ALG9 | c.1027T>G p.L343V | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV67644669; called by muse, mutect2, varscan2
- ALMS1 | c.8077G>T p.E2693* | Nonsense Mutation (SNP) | VAF 32/187 reads (17%) | catalogued as rs1411820884, COSV52513283; called by muse, varscan2
- AMER1 | c.1621A>C p.N541H | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV57662703; called by muse, mutect2, varscan2
- AMER1 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV57662720; called by muse, mutect2, varscan2
- AMPD1 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.93); catalogued as COSV62416866; called by mutect2, varscan2
- AMY2B | c.692A>C p.N231T | Missense Mutation (SNP) | VAF 41/506 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV63715875; called by muse, mutect2
- ANGEL2 | c.885A>C p.K295N | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV64737575; called by muse, mutect2, varscan2
- ANK2 | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as rs772853667, COSV52169808; called by muse, mutect2, varscan2
- ANK2 | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 35/189 reads (19%) | catalogued as rs1162799877, COSV52158299; called by muse, mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANK2 | c.11824C>T p.R3942C | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1344245343; called by muse, mutect2
- ANK3 | c.6596C>A p.T2199N | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.068); catalogued as COSV55065061, COSV55067717; called by muse, mutect2, varscan2
- ANKAR | c.361A>C p.S121R | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1334917028, COSV99854023; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 71/301 reads (24%) | catalogued as COSV51851070; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2164A>G p.T722A | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51851091; called by muse, mutect2, varscan2
- ANKRD1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs780993838, COSV63311064; called by mutect2, varscan2
- ANKRD12 | c.2094G>T p.E698D | Missense Mutation (SNP) | VAF 150/640 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV50831088; called by mutect2, varscan2
- ANKRD24 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs537535275, COSV53672336; called by muse, mutect2, varscan2
- ANKRD36B | c.1525G>T p.D509Y | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749145841, COSV51533596; called by muse, mutect2, varscan2
- ANKRD50 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV72385820; called by muse, mutect2, varscan2
- ANKRD55 | c.1246T>C p.Y416H | Missense Mutation (SNP) | VAF 145/768 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); catalogued as COSV61947793; called by muse, mutect2, varscan2
- ANO2 | c.1144C>A p.L382I (on ENST00000356134 / NM_001278597.3; = p.L386I on NM_001278596.3) | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.624); catalogued as COSV100500159, COSV59024171; called by muse, mutect2, varscan2
- ANO5 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61083785, COSV61087223; called by muse, varscan2
- ANXA13 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as COSV51624462; called by muse, mutect2, varscan2
- AP002512.3 | c.559A>C p.N187H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99687823; called by muse, mutect2, varscan2
- AP2M1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1488778255; called by muse, mutect2, varscan2
- AP3B1 | c.2734C>T p.R912* | Nonsense Mutation (SNP) | VAF 61/288 reads (21%) | catalogued as rs752519227, COSV54877147; called by muse, mutect2, varscan2
- AP3M2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs756052697, COSV51529483; called by mutect2, varscan2
- APC | c.3483T>G p.N1161K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV57355164; called by muse, varscan2
- APLF | c.342-1G>T p.X114_splice | Splice Site (SNP) | VAF 20/117 reads (17%) | catalogued as COSV100376481; called by muse, mutect2, varscan2
- APLP2 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53841780; called by muse, mutect2, varscan2
- APOBEC4 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs867527033, COSV58017983; called by mutect2, varscan2
- ARAP2 | c.3679G>T p.A1227S | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV100394789, COSV58288491; called by muse, mutect2, varscan2
- ARAP2 | c.1810T>G p.F604V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV58284983; called by muse, mutect2, varscan2
- ARAP2 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV58288508; called by muse, mutect2, varscan2
- ARAP2 | c.965-1G>T p.X322_splice | Splice Site (SNP) | VAF 34/180 reads (19%) | catalogued as COSV58282395, COSV58291435; called by muse, mutect2, varscan2
- ARFGEF1 | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 54/320 reads (17%) | catalogued as COSV51610855; called by muse, mutect2, varscan2
- ARGLU1 | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 100/619 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65608292; called by muse, mutect2, varscan2
- ARHGAP11A | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 54/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760030538, COSV64380588; called by muse, mutect2, varscan2
- ARHGAP15 | c.385-1G>T p.X129_splice | Splice Site (SNP) | VAF 15/100 reads (15%) | catalogued as COSV99709319; called by muse, mutect2, varscan2
- ARHGAP19 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as rs771390013, COSV57393724; called by muse, mutect2, varscan2
- ARHGAP31 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1400666120, COSV51795175; called by muse, mutect2, varscan2
- ARHGAP36 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as rs745365369, COSV52264522; called by muse, mutect2, varscan2
- ARHGAP5 | c.3351T>G p.N1117K | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs779050241, COSV61536969; called by muse, mutect2, varscan2
- ARHGAP6 | c.1916A>C p.D639A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV57298079; called by muse, mutect2, varscan2
- ARHGEF11 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 75/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746467759, COSV59352836; called by muse, mutect2, varscan2
- ARID3C | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 54/296 reads (18%) | catalogued as COSV66698043; called by muse, mutect2
- ARID4A | c.3680C>T p.A1227V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs763843963, COSV62164751; called by muse, mutect2, varscan2
- ARID5B | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54423317; called by muse, mutect2
- ARMH4 | c.1669C>A p.L557M | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV50766893; called by muse, mutect2, varscan2
- ARPP21 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1378396699, COSV51801042; called by muse, mutect2, varscan2
- ARRDC4 | c.323T>C p.L108S | Missense Mutation (SNP) | VAF 54/306 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV99164329; called by muse, mutect2, varscan2
- ART3 | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs550091630, COSV61913555; called by mutect2, varscan2
- ART4 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV57452410; called by muse, mutect2, varscan2
- ASB7 | c.944T>G p.F315C | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.869); catalogued as COSV100234894, COSV60417325; called by muse, mutect2, varscan2
- ASB9 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as rs1473100858, COSV66851236; called by muse, mutect2
- ASH1L | c.2972C>A p.T991N | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV64209821; called by mutect2, varscan2
- ASIC5 | c.1112C>A p.S371Y | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101611115; called by muse, mutect2, varscan2
- ASTE1 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs750336679, COSV53909167; called by muse, mutect2, varscan2
- ASTN1 | c.3412G>A p.D1138N | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs778027121, COSV62499427; called by muse, mutect2, varscan2
- ASXL1 | c.1062C>A p.F354L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60111699; called by muse, mutect2, varscan2
- ASXL1 | c.3100A>G p.K1034E | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.841); catalogued as COSV60111707; called by muse, mutect2, varscan2
- ASXL2 | c.993C>A p.F331L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55454364, COSV99712155; called by muse, mutect2, varscan2
- ATAD5 | c.739A>C p.N247H | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58975990; called by muse, mutect2, varscan2
- ATE1 | c.380A>C p.D127A | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV56438194; called by muse, mutect2, varscan2
- ATG2B | c.3154C>A p.L1052I | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV63422145, COSV63424081; called by muse, mutect2
- ATG4C | c.1346G>T p.R449I | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs749357381, COSV58603833, COSV58606729; called by muse, mutect2, varscan2
- ATM | c.2933C>A p.S978Y | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53781594; called by muse, mutect2, varscan2
- ATM | c.7669T>G p.L2557V | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV53752809; called by muse, mutect2, varscan2
- ATP10A | c.666C>A p.F222L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as COSV100790999, COSV63517451; called by muse, mutect2, varscan2
- ATP10A | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs773442220, COSV100791000; called by muse, mutect2, varscan2
- ATP10B | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 69/366 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs201710345; called by muse, mutect2, varscan2
- ATP12A | c.2136G>T p.Q712H | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54518553; called by muse, mutect2, varscan2
- ATP13A4 | c.2327T>C p.I776T | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV61321666; called by muse, mutect2, varscan2
- ATP13A5 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.275); catalogued as COSV60868697; called by muse, mutect2, varscan2
- ATP2A2 | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV57875702; called by muse, mutect2, varscan2
- ATP2C2 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 19/153 reads (12%) | catalogued as COSV52297669; called by muse, mutect2, varscan2
- ATP8A2 | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 71/415 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54960468; called by muse, mutect2, varscan2
- ATP8B1 | c.3373C>A p.L1125I | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52177288; called by muse, mutect2, varscan2
- ATP8B4 | c.1443G>T p.E481D | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99464374; called by muse, mutect2
- ATRX | c.6938T>C p.L2313S | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV100970277, COSV64874125; called by muse, mutect2, varscan2
- ATRX | c.5478C>A p.F1826L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100970118; called by muse, mutect2
- ATRX | c.3835G>T p.E1279* | Nonsense Mutation (SNP) | VAF 51/272 reads (19%) | catalogued as COSV100970278; called by muse, mutect2, varscan2
- ATXN3L | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV101019339; called by muse, mutect2
- AUTS2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61412662; called by muse, mutect2, varscan2
- AXDND1 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 25/532 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100858654; called by muse, mutect2
- B2M | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62564953; called by muse, mutect2, varscan2
- BACE2 | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV100160630; called by muse, mutect2
- BAG5 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1488802882, COSV54571459; called by mutect2, varscan2
- BAG5 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV54571467; called by muse, mutect2, varscan2
- BANK1 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 35/167 reads (21%) | catalogued as COSV59845318, COSV59849860; called by muse, mutect2, varscan2
- BAP1 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs951076425; ClinVar: uncertain significance; called by muse, mutect2
- BARD1 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758749603, COSV53613427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARHL2 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1196217355; called by muse, mutect2, varscan2
- BBOX1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1379464119, COSV54191958; called by muse, mutect2, varscan2
- BCL2A1 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 78/390 reads (20%) | catalogued as COSV51213429, COSV51213657; called by muse, varscan2
- BCL2A1 | c.347A>C p.K116T | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV51213158; called by muse, varscan2
- BCL7B | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.238); catalogued as rs782334386, COSV56270029; called by muse, mutect2, varscan2
- BCL9 | c.1026dup p.T343Hfs*34 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | catalogued as rs1553204401; called by mutect2, varscan2
- BCOR | c.4734C>A p.F1578L (on ENST00000378444 / NM_001123385.2; = p.F1544L on NM_017745.6) | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60710884; called by muse, mutect2, varscan2
- BCOR | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs367848648, COSV60708819; called by muse, varscan2
- BCOR | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60701079; called by muse, varscan2
- BDP1 | c.2419C>A p.L807I | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.088); catalogued as rs745904337; called by muse, mutect2
- BEND2 | c.1181-1G>T p.X394_splice | Splice Site (SNP) | VAF 18/312 reads (6%) | catalogued as COSV101191882; called by muse, mutect2
- BEND3 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as rs782731122, COSV64681450; called by muse, mutect2, varscan2
- BEST3 | c.1849C>A p.L617I | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.146); catalogued as rs745371418, COSV58302624; called by muse, mutect2, varscan2
- BEST3 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.101); catalogued as rs1326380921, COSV56995066; called by muse, mutect2, varscan2
- BIRC6 | c.6916G>T p.E2306* | Nonsense Mutation (SNP) | VAF 29/132 reads (22%) | catalogued as COSV70201730; called by muse, mutect2, varscan2
- BIRC6 | c.9967G>A p.V3323I | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs758763656, COSV70201738; called by muse, mutect2, varscan2
- BIRC6 | c.13486C>T p.R4496W | Missense Mutation (SNP) | VAF 91/281 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV70201627; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1899C>A p.F633L | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV63244998; called by muse, mutect2, varscan2
- BLM | c.3260T>G p.F1087C | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV61925107; called by muse, mutect2, varscan2
- BLNK | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56409997; called by muse, mutect2, varscan2
- BMP3 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1435451372, COSV51081644; called by muse, mutect2, varscan2
- BMPR1B | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.099); catalogued as COSV52782846; called by muse, mutect2
- BMPR1B | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV52778958; called by muse, mutect2, varscan2
- BMS1 | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV65734385; called by muse, mutect2, varscan2
- BOD1L1 | c.9146C>T p.A3049V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs769512613, COSV50008166; called by muse, mutect2, varscan2
- BPIFB4 | c.251T>G p.I84S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100971462; called by muse, mutect2, varscan2
- BRCA2 | c.963A>C p.Q321H | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs276174927, BM1120885, COSV66456474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.10151G>A p.R3384Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as rs80358397, COSV66336721; ClinVar: uncertain significance; called by mutect2, varscan2
- BRD1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778657442, COSV53458909; called by muse, mutect2, varscan2
- BRD8 | c.2758G>T p.E920* | Nonsense Mutation (SNP) | VAF 60/348 reads (17%) | catalogued as COSV50154806; called by muse, mutect2, varscan2
- BRDT | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303707788, COSV61770993; called by muse, mutect2, varscan2
- BRI3BP | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV58296524; called by muse, mutect2
- BRINP1 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56304193; called by muse, mutect2, varscan2
- BRWD3 | c.3242C>A p.S1081Y | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.265); catalogued as COSV64750004; called by muse, mutect2, varscan2
- BRWD3 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs898480653, COSV64750023; called by muse, mutect2, varscan2
- BRWD3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV100955816, COSV64748283; called by muse, mutect2
- BRWD3 | c.485T>C p.F162S | Missense Mutation (SNP) | VAF 56/398 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV64750030; called by muse, mutect2, varscan2
- BTAF1 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769390194, COSV56439783; called by muse, mutect2, varscan2
- BTAF1 | c.3241G>T p.E1081* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as COSV56435810; called by muse, mutect2, varscan2
- BTBD11 | c.1165C>A p.L389I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.396); catalogued as COSV55027627; called by muse, mutect2, varscan2
- BTN3A2 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV62687580; called by muse, mutect2
- BTNL8 | c.461G>C p.C154S | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99180435; called by muse, mutect2, varscan2
- BUB1B | c.1187T>G p.M396R | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV55013957; called by muse, mutect2, varscan2
- BVES | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58948552, COSV58949077; called by muse, mutect2, varscan2
- C11orf16 | c.1392G>T p.K464N | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV55149633; called by muse, mutect2
- C11orf54 | c.445T>G p.C149G | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as COSV58681006; called by muse, mutect2, varscan2
- C12orf50 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53896461; called by muse, varscan2
- C12orf54 | c.280T>G p.L94V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.112); catalogued as COSV58360522; called by mutect2, varscan2
- C17orf75 | c.1032T>G p.H344Q | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56753145; called by muse, mutect2, varscan2
- C18orf54 | c.993C>A p.F331L | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV55618555; called by muse, mutect2, varscan2
- C1S | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV100196630, COSV61071302; called by muse, mutect2, varscan2
- C1orf226 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63395851; called by muse, mutect2, varscan2
- C2orf42 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV52451056; called by muse, mutect2, varscan2
- C2orf49 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 57/345 reads (17%) | catalogued as COSV51528227; called by muse, mutect2, varscan2
- C2orf69 | c.953A>C p.K318T | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV60666781; called by muse, mutect2, varscan2
- C4BPA | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV65536707; called by muse, mutect2, varscan2
- C6 | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV54712510; called by muse, mutect2, varscan2
- C6orf136 | c.502G>A p.D168N (on ENST00000376473 / NM_001109938.3; = p.D34N on NM_145029.4) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); catalogued as rs771615967, COSV53314831; called by muse, mutect2, varscan2
- C7 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 39/201 reads (19%) | catalogued as COSV57473700; called by muse, mutect2, varscan2
- C7orf33 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as COSV100188975, COSV61023347; called by muse, varscan2
- C8A | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV63484810, COSV63486233; called by muse, mutect2, varscan2
- C9 | c.876A>C p.K292N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV54675659; called by muse, mutect2, varscan2
- CACHD1 | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.982); catalogued as COSV51555669; called by muse, mutect2, varscan2
- CACHD1 | c.2097C>A p.F699L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV51555678; called by muse, mutect2, varscan2
- CACNA1A | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | catalogued as rs886042230, COSV64194925; called by muse, mutect2
- CACNA1B | c.5178G>T p.L1726F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53133119; called by muse, mutect2, varscan2
- CACNA1E | c.2704G>T p.G902* | Nonsense Mutation (SNP) | VAF 12/143 reads (8%) | catalogued as COSV62382319; called by muse, mutect2
- CACNA1E | c.3351G>T p.K1117N | Missense Mutation (SNP) | VAF 83/389 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as COSV62402253; called by muse, mutect2, varscan2
- CACNA1E | c.5143C>A p.L1715I | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62402257; called by muse, mutect2, varscan2
- CACNA1S | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1287772954, COSV100754794; called by muse, mutect2, varscan2
- CACNA2D1 | c.2621T>G p.F874C (on ENST00000356253 / NM_001366867.1; = p.F862C on NM_000722.4) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62383163; called by muse, mutect2, varscan2
- CACNA2D1 | c.1376T>G p.V459G | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62383168; called by muse, mutect2, varscan2
- CACNA2D3 | c.2626G>T p.D876Y | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV55560133; called by muse, varscan2
- CACNG3 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 13/137 reads (9%) | catalogued as COSV50072151, COSV50073264; called by muse, mutect2
- CADPS | c.2086G>T p.D696Y | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99336714; called by muse, varscan2
- CALD1 | c.2194A>C p.N732H (on ENST00000361675 / NM_033138.4; = p.N477H on NM_004342.7) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62649478; called by muse, mutect2, varscan2
- CAPN2 | c.399A>C p.E133D | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54337291; called by muse, mutect2, varscan2
- CASP8AP2 | c.3708T>A p.N1236K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs763162486, COSV52748127; called by muse, mutect2, varscan2
- CASQ2 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54771562; called by muse, mutect2, varscan2
- CASQ2 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1231549562; called by muse, mutect2
- CASS4 | c.643-1G>T p.X215_splice | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100825013; called by mutect2, varscan2
- CATSPERE | c.1628T>G p.F543C | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63679228; called by muse, mutect2, varscan2
- CAVIN2 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 81/274 reads (30%) | catalogued as COSV58424663; called by muse, mutect2, varscan2
- CBX1 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 28/646 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV56682110; called by muse, mutect2
- CCDC105 | c.1097A>G p.K366R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.35); catalogued as COSV99479796; called by muse, mutect2, varscan2
- CCDC112 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 48/285 reads (17%) | catalogued as COSV65473426; called by muse, mutect2, varscan2
- CCDC146 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs148455218, COSV53547020; called by mutect2, varscan2
- CCDC158 | c.3056C>T p.S1019F | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs772436559, COSV66356458, COSV66357237; called by muse, mutect2, varscan2
- CCDC174 | c.953-1G>T p.X318_splice | Splice Site (SNP) | VAF 17/145 reads (12%) | catalogued as COSV100358480; called by muse, mutect2, varscan2
- CCDC22 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 21/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66052026; called by muse, mutect2
- CCDC32 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | catalogued as rs1451366732, COSV63635134; called by muse, mutect2, varscan2
- CCDC40 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV53898100; called by muse, mutect2, varscan2
- CCDC66 | c.746C>A p.T249N (on ENST00000394672 / NM_001353147.1; = p.T215N on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58305505; called by muse, mutect2, varscan2
- CCDC68 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 30/161 reads (19%) | catalogued as COSV61604031; called by muse, mutect2, varscan2
- CCDC7 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as rs762095619, COSV53227495, COSV99511238; called by muse, mutect2, varscan2
- CCDC73 | c.1375+2T>C p.X459_splice | Splice Site (SNP) | VAF 19/108 reads (18%) | catalogued as COSV100066810; called by muse, mutect2, varscan2
- CCDC82 | c.1597T>G p.F533V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV53594122; called by muse, mutect2, varscan2
- CCDC82 | c.818A>C p.D273A | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV53594132; called by muse, mutect2, varscan2
- CCDC82 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 27/466 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99567149; called by muse, mutect2
- CCDC83 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 11/182 reads (6%) | catalogued as rs1292149589, COSV54702941; called by muse, mutect2
- CCER1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.41); catalogued as COSV62647167; called by muse, mutect2, varscan2
- CCNB3 | c.2800A>C p.N934H | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.554); catalogued as COSV52075463; called by muse, mutect2, varscan2
- CCNH | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99907217; called by muse, mutect2
- CCNL1 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 74/392 reads (19%) | catalogued as COSV55819736; called by muse, mutect2, varscan2
- CCNT2 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 81/302 reads (27%) | catalogued as COSV51472643; called by muse, mutect2, varscan2
- CCR4 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58382816; called by muse, mutect2, varscan2
- CCR7 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs759676455, COSV55849835; called by muse, mutect2, varscan2
- CCR9 | c.38T>C p.M13T (on ENST00000357632 / NM_031200.3; = p.M1? on NM_006641.4) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs749729442, COSV62940409; called by mutect2, varscan2
- CCSER1 | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61441894; called by mutect2, varscan2
- CCT6B | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58489925; called by muse, mutect2, varscan2
- CD101 | c.1604A>C p.K535T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.494); catalogued as COSV56718962; called by muse, mutect2, varscan2
- CD101 | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 50/252 reads (20%) | catalogued as COSV56717297, COSV56718974; called by muse, mutect2, varscan2
- CD33 | c.175T>G p.Y59D | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51802680; called by muse, mutect2, varscan2
- CD69 | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV57303034; called by muse, mutect2, varscan2
- CD72 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV52411572; called by muse, mutect2, varscan2
- CDAN1 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768892869, COSV62332744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC14A | c.75G>T p.R25S | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV60559839; called by muse, mutect2, varscan2
- CDC27 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1238314971, COSV50366964; called by muse, mutect2, varscan2
- CDC40 | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57010533; called by muse, mutect2, varscan2
- CDC73 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV66465795; called by muse, mutect2, varscan2
- CDH12 | c.1604A>C p.K535T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV66386383, COSV66417587; called by muse, mutect2, varscan2
- CDH20 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV53012389; called by muse, mutect2
- CDH23 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); catalogued as COSV54929104, COSV99818254; called by mutect2, varscan2
- CDH8 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs771617779, COSV54865437; called by mutect2, varscan2
- CDH9 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs768954953, COSV50261316, COSV50266286; called by muse, mutect2, varscan2
- CDK11A | c.1889C>T p.S630L (on ENST00000378633 / NM_001313896.2; = p.S627L on NM_024011.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757293035, COSV52307726, COSV99319203; called by muse, varscan2
- CDK12 | c.2614C>T p.Q872* | Nonsense Mutation (SNP) | VAF 51/304 reads (17%) | catalogued as COSV71001376; called by muse, mutect2, varscan2
- CDK13 | c.3940G>T p.D1314Y | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV51702419; called by muse, mutect2, varscan2
- CDK16 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52092673; called by muse, mutect2, varscan2
- CDKN1B | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 13/101 reads (13%) | catalogued as CM023042, COSV57430128; called by muse, mutect2, varscan2
- CDS1 | c.430A>C p.T144P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55688771; called by muse, mutect2, varscan2
- CDS1 | c.642C>T p.F214= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as rs375840719; called by mutect2, varscan2
- CDYL2 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.368); catalogued as COSV73648034; called by muse, mutect2, varscan2
- CEACAM8 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV54990974, COSV99747576; called by muse, mutect2
- CECR2 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52841089; called by muse, mutect2, varscan2
- CECR2 | c.2587C>T p.P863S (on ENST00000342247 / NM_001290047.2; = p.P680S on NM_001290046.1) | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs1569154189, COSV52843909; called by muse, mutect2, varscan2
- CEMIP2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.223); catalogued as rs548434215, COSV65484674; called by muse, mutect2, varscan2
- CENPE | c.4036T>G p.S1346A | Missense Mutation (SNP) | VAF 96/492 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54383316; called by muse, mutect2, varscan2
- CENPF | c.3124A>C p.K1042Q | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV65276118; called by muse, varscan2
- CENPF | c.8260G>T p.E2754* | Nonsense Mutation (SNP) | VAF 48/236 reads (20%) | catalogued as COSV65276121; called by muse, mutect2, varscan2
- CENPF | c.8576A>G p.E2859G | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65276124, COSV65276821; called by muse, varscan2
- CENPU | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55658220; called by muse, mutect2, varscan2
- CEP104 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 16/155 reads (10%) | catalogued as rs145420390, COSV65511801; called by mutect2, varscan2
- CEP152 | c.2887G>T p.E963* | Nonsense Mutation (SNP) | VAF 69/367 reads (19%) | catalogued as COSV57860890; called by muse, mutect2, varscan2
- CEP152 | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57860895; called by muse, mutect2, varscan2
- CEP164 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99632776; called by muse, mutect2
- CEP83 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1288256034, COSV60406406; called by muse, mutect2
- CEP95 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.235); catalogued as rs782452611, COSV101616308, COSV73609433; called by muse, mutect2, varscan2
- CERCAM | c.796C>A p.R266S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.094); catalogued as COSV100863784, COSV100864127; called by muse, mutect2, varscan2
- CERS3 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52570389; called by muse, mutect2, varscan2
- CERS3 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52565563; called by muse, mutect2, varscan2
- CERT1 | c.1350C>A p.F450L (on ENST00000405807 / NM_001130105.1; = p.F322L on NM_005713.3) | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54665193; called by muse, mutect2
- CES1 | c.1203G>T p.E401D (on ENST00000361503 / NM_001025194.2; = p.E400D on NM_001266.5) | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV62086519; called by muse, mutect2
- CETN1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV59121768; called by muse, varscan2
- CFAP157 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs551402620, COSV58852076; called by muse, mutect2, varscan2
- CFAP206 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as rs370690253; called by mutect2, varscan2
- CFAP206 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV51535044; called by muse, mutect2, varscan2
- CFAP299 | c.589C>A p.L197I | Missense Mutation (SNP) | VAF 110/465 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100811630, COSV63881038; called by muse, mutect2, varscan2
- CFAP43 | c.4052C>A p.A1351D | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV63852902; called by muse, mutect2, varscan2
- CFAP43 | c.3500A>G p.K1167R | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs771756090, COSV63853585; called by muse, mutect2, varscan2
- CFAP47 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV52887176; called by muse, mutect2, varscan2
- CFAP54 | c.5716+2T>C p.X1906_splice | Splice Site (SNP) | VAF 15/263 reads (6%) | catalogued as COSV61571539; called by muse, mutect2
- CFAP91 | c.360-1G>T p.X120_splice | Splice Site (SNP) | VAF 83/459 reads (18%) | catalogued as COSV56343699, COSV99846736; called by muse, mutect2, varscan2
- CFAP94 | c.1016A>C p.K339T (on ENST00000320267 / NM_001352064.2; = p.K345T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.355); catalogued as COSV57233691; called by muse, mutect2, varscan2
- CFDP1 | c.403-1G>A p.X135_splice | Splice Site (SNP) | VAF 51/148 reads (34%) | catalogued as COSV52208578; called by muse, mutect2, varscan2
- CHD2 | c.4229A>C p.D1410A | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV67711002; called by muse, mutect2
- CHD4 | c.1676G>A p.R559Q (on ENST00000357008 / NM_001363606.2; = p.R572Q on NM_001273.5) | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58904370; called by muse, mutect2, varscan2
- CHD5 | c.1764G>T p.K588N | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV52413279; called by muse, mutect2
- CHD8 | c.4179T>G p.N1393K (on ENST00000646647 / NM_001170629.2; = p.N1114K on NM_020920.4) | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63219305; called by muse, mutect2, varscan2
- CHD9 | c.5393A>G p.N1798S | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1381047417, COSV54612189; called by muse, mutect2, varscan2
- CHGB | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs560272361, COSV66760876; called by muse, mutect2, varscan2
- CHRDL1 | c.1005C>A p.F335L (on ENST00000372045; = p.F341L on NM_145234.4) | Missense Mutation (SNP) | VAF 73/374 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54326274; called by muse, mutect2, varscan2
- CHRDL1 | c.212G>A p.R71Q (on ENST00000372045; = p.R77Q on NM_145234.4) | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs149609884, COSV54326285, COSV99488325; called by muse, mutect2, varscan2
- CHRNA6 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371233399; called by muse, mutect2, varscan2
- CHST1 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as rs1391430094, COSV100346531, COSV57324224; called by muse, mutect2, varscan2
- CHST13 | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60042548; called by muse, mutect2, varscan2
- CHST15 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1211367226; called by muse, mutect2
- CHST2 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1042624925, COSV100536034; called by muse, mutect2
- CHST9 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52439630, COSV52441080; called by muse, mutect2, varscan2
- CIBAR2 | c.546T>G p.F182L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.162); catalogued as COSV73320638; called by muse, mutect2, varscan2
- CKAP2L | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV100198560, COSV56696949; called by muse, mutect2, varscan2
- CLCA1 | c.1877T>G p.V626G | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52328793; called by muse, mutect2, varscan2
- CLCA4 | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1441848033, COSV99760322; called by muse, mutect2
- CLCN5 | c.1044G>T p.K348N | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV56583304, COSV56585060; called by muse, mutect2, varscan2
- CLDN16 | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 60/750 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV53228245, COSV99290046; called by muse, mutect2
- CLDN2 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.869); catalogued as COSV61020942; called by muse, mutect2, varscan2
- CLDN8 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs994122095, COSV54526331; called by muse, mutect2, varscan2
- CLDN8 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 10/136 reads (7%) | catalogued as COSV54526083, COSV54526345; called by muse, mutect2
- CLEC16A | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1567530329, COSV68500406; called by muse, mutect2, varscan2
- CLEC4A | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.071); catalogued as COSV57562189; called by muse, mutect2, varscan2
- CLHC1 | c.365+1G>T p.X122_splice | Splice Site (SNP) | VAF 92/502 reads (18%) | catalogued as COSV100811477; called by muse, varscan2
- CLIP1 | c.2017G>A p.E673K (on ENST00000620786 / NM_001247997.1; = p.E662K on NM_002956.2) | Missense Mutation (SNP) | VAF 121/547 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs201352592; called by muse, mutect2, varscan2
- CLK3 | c.1243C>A p.L415I (on ENST00000395066 / NM_001130028.1; = p.L267I on NM_003992.4) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.353); catalogued as COSV59340801; called by muse, mutect2, varscan2
- CLYBL | c.534T>G p.N178K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV59223623; called by muse, mutect2
- CMSS1 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV70438865; called by muse, mutect2, varscan2
- CMYA5 | c.2884A>C p.T962P | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV71406984; called by muse, mutect2, varscan2
- CMYA5 | c.4237C>A p.L1413I | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV71406988; called by muse, mutect2, varscan2
- CMYA5 | c.5242T>G p.L1748V | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.409); catalogued as rs749328624, COSV71406992; called by mutect2, varscan2
- CMYA5 | c.6628G>A p.V2210I | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as rs751513243, COSV71404031; called by muse, varscan2
- CMYA5 | c.9711T>G p.Y3237* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV71406998; called by muse, mutect2, varscan2
- CNGA1 | c.1979A>C p.K660T | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV62054982; called by muse, mutect2, varscan2
- CNGA1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 72/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198139574, COSV62053154; called by muse, mutect2, varscan2
- CNGA2 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780670790, COSV61705135; called by muse, mutect2, varscan2
- CNOT6L | c.800C>A p.S267* (on ENST00000504123 / NM_001286790.2; = p.S262* on NM_144571.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/285 reads (6%) | catalogued as COSV99361551; called by muse, mutect2
- CNPY1 | c.44G>T p.R15I | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs1200944745, COSV58787694; called by muse, mutect2, varscan2
- CNPY2 | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.017); catalogued as rs1363961259, COSV56264599; called by muse, mutect2, varscan2
- CNTF | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100284377; called by muse, mutect2
- CNTN1 | c.971G>T p.R324I | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs148624625, COSV61641574; called by muse, mutect2, varscan2
- CNTN1 | c.1678T>G p.F560V | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61641583; called by muse, mutect2
- CNTN5 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as COSV54324377; called by muse, mutect2, varscan2
- CNTN5 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.774); catalogued as rs1010130853, COSV54303038, COSV99676123; called by muse, mutect2, varscan2
- COBLL1 | c.2334G>T p.K778N (on ENST00000392717; = p.K740N on NM_014900.5) | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs377161034, COSV52074719; called by muse, mutect2, varscan2
- COG4 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs149620212; called by mutect2, varscan2
- COL11A2 | c.2323G>A p.G775R (on ENST00000341947 / NM_080680.3; = p.G668R on NM_080679.2) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59498606; called by muse, mutect2, varscan2
- COL12A1 | c.7576G>A p.A2526T | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV59399258; called by muse, varscan2
- COL14A1 | c.4771G>A p.A1591T | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs370064596; called by muse, mutect2, varscan2
- COL24A1 | c.1127A>C p.N376T | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV65308530; called by muse, mutect2, varscan2
- COL5A2 | c.3736G>T p.D1246Y | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV66410917; called by muse, mutect2
- COLGALT2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs757064316, COSV62299839; called by mutect2, varscan2
- COMMD2 | c.290A>G p.K97R | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV101511896; called by muse, mutect2
- COPS6 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57997209; called by muse, mutect2, varscan2
- CORO2B | c.1187C>A p.S396Y | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55954398; called by muse, mutect2, varscan2
- CP | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 53/212 reads (25%) | catalogued as COSV52829774; called by muse, mutect2, varscan2
- CPA6 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775233588, COSV52721227; called by muse, mutect2, varscan2
- CPD | c.3878T>G p.I1293R | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56713958; called by muse, mutect2, varscan2
- CPE | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 14/160 reads (9%) | catalogued as COSV68582461; called by muse, mutect2
- CPED1 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as rs202229385, COSV60005795; called by muse, mutect2, varscan2
- CPED1 | c.2314C>A p.L772M | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV60012901; called by muse, mutect2
- CPQ | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV55150888; called by muse, mutect2, varscan2
- CPS1 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 25/145 reads (17%) | catalogued as COSV51801791; called by muse, mutect2, varscan2
- CPXCR1 | c.890G>T p.S297I | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV52160835; called by muse, mutect2, varscan2
- CPXM1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 64/347 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV66045924; called by muse, mutect2, varscan2
- CPXM2 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53864829, COSV53871457; called by muse, mutect2, varscan2
- CR2 | c.2402A>C p.K801T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV65508348; called by muse, mutect2, varscan2
- CRIM1 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54866922; called by muse, mutect2, varscan2
- CRNKL1 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 36/166 reads (22%) | catalogued as COSV58548136; called by muse, mutect2, varscan2
- CRTAM | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs148256561, COSV99911885; called by muse, mutect2, varscan2
- CSMD1 | c.1885G>T p.D629Y (on ENST00000520002; = p.D628Y on NM_033225.6) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59298103, COSV59341653; called by muse, mutect2, varscan2
- CSMD2 | c.1985A>G p.H662R | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53926304; called by muse, mutect2, varscan2
- CSMD3 | c.3578G>A p.R1193Q (on ENST00000297405 / NM_001363185.1; = p.R1089Q on NM_052900.3) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs1323845975, COSV52111209; called by muse, mutect2, varscan2
- CSRNP1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200194534, COSV56188870; called by muse, mutect2, varscan2
- CTAGE6 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as COSV101417824; called by mutect2, varscan2
- CTAGE6 | c.1049A>C p.E350A | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV101417825; called by muse, mutect2, varscan2
- CTCFL | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772424129, COSV54770682; called by muse, mutect2, varscan2
- CTNNA2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.948); catalogued as rs574924497, COSV63579296; called by muse, mutect2, varscan2
- CTNNB1 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62705582; called by muse, mutect2, varscan2
- CTPS2 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.06); catalogued as COSV100826732; called by muse, mutect2
- CTTNBP2 | c.4514C>A p.S1505Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.11); catalogued as COSV50414575; called by muse, mutect2, varscan2
- CTXN3 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1225404731, COSV65218585; called by muse, mutect2, varscan2
- CWF19L1 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV100821474; called by muse, mutect2
- CWF19L2 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs550302523, COSV56514998; called by muse, mutect2, varscan2
- CXorf58 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 88/572 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV64858251, COSV64858484; called by muse, mutect2, varscan2
- CYB5R4 | c.879C>A p.F293L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV63751204; called by muse, mutect2, varscan2
- CYLC1 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 82/407 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV61413231; called by muse, mutect2, varscan2
- CYLC1 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 99/507 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61413240; called by muse, mutect2, varscan2
- CYP11B1 | c.426G>T p.L142F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52828381; called by muse, mutect2
- CYP2C18 | c.706A>C p.N236H | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV53671095; called by muse, mutect2, varscan2
- CYP2U1 | c.1127-1G>T p.X376_splice | Splice Site (SNP) | VAF 14/86 reads (16%) | catalogued as COSV60548252; called by muse, mutect2, varscan2
- CYP39A1 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV51496884; called by muse, mutect2, varscan2
- CYP4F12 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as COSV61174674; called by muse, mutect2, varscan2
- CYP4F22 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761963345, COSV54107667; called by muse, mutect2, varscan2
- CYSLTR2 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV56166243; called by muse, mutect2, varscan2
- DAAM1 | c.2558A>G p.N853S | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as COSV62837487; called by muse, mutect2
- DAB1 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 64/203 reads (32%) | catalogued as COSV59730609; called by muse, mutect2, varscan2
- DAPK1 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs772431146, COSV63788568, COSV63788808; called by muse, mutect2, varscan2
- DAW1 | c.1004G>T p.R335I | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV59366530, COSV59369610; called by muse, varscan2
- DCAF10 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs767043246, COSV54288016; called by muse, mutect2, varscan2
- DCAF12L1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV100948157; called by muse, mutect2, varscan2
- DCAF4L2 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60477184, COSV60480639; called by muse, mutect2, varscan2
- DCAF7 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV60407981; called by muse, mutect2, varscan2
- DCHS1 | c.6319C>A p.L2107I | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.621); catalogued as COSV100202576; called by muse, mutect2, varscan2
- DCLRE1A | c.1576T>G p.L526V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV63749036; called by muse, mutect2, varscan2
- DCLRE1C | c.4A>C p.S2R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63184134; called by muse, mutect2, varscan2
- DCN | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs751102416, COSV50007765, COSV50008884; called by mutect2, varscan2
- DCP2 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 25/176 reads (14%) | catalogued as COSV66617419; called by muse, varscan2
- DCT | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274035879, COSV65469838; called by muse, mutect2, varscan2
- DDB2 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs375649516; called by mutect2, varscan2
- DDR2 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63372039; called by muse, varscan2
- DDX6 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50588745; called by muse, mutect2, varscan2
- DEFB136 | c.123C>A p.F41L | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV66363943; called by muse, mutect2, varscan2
- DEGS1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60379532; called by muse, mutect2, varscan2
- DENND4A | c.3914C>A p.S1305* | Nonsense Mutation (SNP) | VAF 20/148 reads (14%) | catalogued as COSV71266321; called by muse, mutect2, varscan2
- DENND5B | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1488658943, COSV60900651, COSV60902248; called by muse, mutect2, varscan2
- DEPDC1 | c.1724C>A p.S575Y | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV100920539; called by muse, mutect2
- DEUP1 | c.1729C>A p.L577I | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769163934, COSV53213533; called by muse, mutect2, varscan2
- DGKD | c.397G>T p.E133* (on ENST00000264057 / NM_152879.3; = p.E89* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 67/402 reads (17%) | catalogued as rs199985859, COSV51038365; called by muse, mutect2, varscan2
- DGKH | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs370149879; called by muse, mutect2, varscan2
- DGKI | c.3040C>A p.L1014M | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55957851; called by muse, mutect2, varscan2
- DGKK | c.2921C>A p.S974Y | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101052930; called by muse, mutect2, varscan2
- DGKK | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV101052892; called by muse, mutect2, varscan2
- DHFR | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1456478807, COSV71485479; called by muse, varscan2
- DHRS2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs562246921, COSV51632626; called by muse, mutect2, varscan2
- DHX36 | c.1616G>T p.R539I | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); catalogued as COSV57672456, COSV57676064; called by muse, mutect2, varscan2
- DHX40 | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 26/125 reads (21%) | catalogued as COSV99232812; called by muse, mutect2, varscan2
- DHX58 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV52426682; called by muse, mutect2, varscan2
- DICER1 | c.2876A>C p.K959T | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV100602677, COSV58620076; called by muse, mutect2
- DISP2 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs150424497; called by muse, mutect2, varscan2
- DKC1 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65729807; called by muse, mutect2, varscan2
- DLL3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770966935, COSV52693963; called by muse, mutect2, varscan2
- DMC1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745397961, COSV53258386; called by muse, mutect2, varscan2
- DMD | c.5627C>A p.S1876Y | Missense Mutation (SNP) | VAF 33/477 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV63767582, COSV63791573; called by muse, mutect2
- DMD | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881175; called by muse, mutect2, varscan2
- DMGDH | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs369589026; called by muse, mutect2, varscan2
- DMXL1 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1225994331, COSV60714858; called by muse, mutect2, varscan2
- DMXL1 | c.6206C>T p.A2069V | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV60714864; called by muse, mutect2, varscan2
- DNAH10 | c.12799G>T p.E4267* (on ENST00000409039; = p.E4206* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV53020358; called by muse, mutect2, varscan2
- DNAH11 | c.9346C>A p.L3116I | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60963286; called by muse, mutect2, varscan2
- DNAH11 | c.12950C>T p.S4317F | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV60963293; called by muse, varscan2
- DNAH2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1207139710; called by muse, mutect2
- DNAH5 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs200704983, COSV54220726; called by muse, mutect2, varscan2
- DNAH6 | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 29/154 reads (19%) | catalogued as COSV52868108; called by muse, mutect2, varscan2
- DNAH8 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100543959; called by muse, mutect2
- DNAH8 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV59458288; called by muse, mutect2, varscan2
- DNAH8 | c.9973G>T p.V3325L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV59458305; called by muse, mutect2, varscan2
- DNAH9 | c.2408G>T p.R803I | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs753142472, COSV52336899, COSV52340773; called by muse, mutect2, varscan2
- DNAI3 | c.278T>G p.I93S | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV54000603, COSV54003769; called by muse, varscan2
- DNAI3 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54005751, COSV54007468; called by muse, mutect2
- DNAJB8 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as rs534274395, COSV59878383; called by mutect2, varscan2
- DNAJC10 | c.2250C>A p.F750L | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51135745; called by muse, mutect2, varscan2
- DNAJC13 | c.3481G>T p.D1161Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53453197; called by mutect2, varscan2
- DNAJC18 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs201230885, COSV57415758; called by muse, mutect2, varscan2
- DNAJC2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1044150804, COSV50791729; called by muse, mutect2, varscan2
- DNAJC25 | c.454A>C p.I152L | Missense Mutation (SNP) | VAF 113/674 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.203); catalogued as COSV57957125; called by muse, varscan2
- DNAJC28 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 48/267 reads (18%) | catalogued as rs138072076; called by muse, mutect2, varscan2
- DNAJC5B | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 33/176 reads (19%) | catalogued as COSV52538186; called by muse, mutect2, varscan2
- DNM1 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1420929016, COSV57852937; called by muse, mutect2, varscan2
- DNM1L | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751127554, COSV56771938; called by muse, mutect2, varscan2
- DNMT3B | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs1282274366, COSV52419727, COSV99145838; called by muse, mutect2, varscan2
- DNTT | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV64523216; called by muse, varscan2
- DOCK2 | c.879T>G p.I293M | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV56967314; called by muse, mutect2, varscan2
- DOCK2 | c.4940C>A p.S1647Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV56967327; called by muse, mutect2, varscan2
- DOCK3 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.54); catalogued as COSV56512700; called by muse, mutect2, varscan2
- DOCK3 | c.1128T>C p.G376= | Splice Region (SNP) | VAF 105/379 reads (28%) | catalogued as rs1187432954, COSV56530654; called by muse, mutect2, varscan2
- DOCK3 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1228911523, COSV56516212; called by muse, mutect2, varscan2
- DOCK4 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.262); catalogued as COSV70322791; called by muse, mutect2, varscan2
- DPP10 | c.1875G>T p.K625N | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV59696363; called by muse, varscan2
- DPPA2 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV101524775, COSV72118156; called by muse, mutect2, varscan2
- DQX1 | c.1797C>A p.Y599* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as COSV52046385; called by muse, mutect2, varscan2
- DRC1 | c.1881G>T p.K627N | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV55507511; called by muse, mutect2, varscan2
- DRP2 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV65810778; called by muse, mutect2, varscan2
- DSC1 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 29/131 reads (22%) | catalogued as COSV57147530; called by muse, mutect2, varscan2
- DSCAML1 | c.4102C>T p.R1368W (on ENST00000321322; = p.R1308W on NM_020693.4) | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58381992; called by muse, mutect2, varscan2
- DSCAML1 | c.451G>A p.A151T (on ENST00000321322; = p.A91T on NM_020693.4) | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); catalogued as rs773114652, COSV58397545; called by muse, mutect2, varscan2
- DSG4 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as rs886053705, COSV57388902; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.14492A>G p.E4831G (on ENST00000361203 / NM_001374722.1; = p.E2419G on NM_015548.5) | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55023108; called by muse, mutect2, varscan2
- DST | c.11413G>A p.E3805K (on ENST00000361203 / NM_001374722.1; = p.E1393K on NM_015548.5) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV55008432, COSV55037893; called by muse, mutect2, varscan2
- DST | c.10601A>C p.K3534T | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99752867; called by muse, mutect2, varscan2
- DUOX2 | c.2640C>A p.F880L | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1160134983, COSV66530507; called by muse, mutect2, varscan2
- DUSP26 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 46/208 reads (22%) | catalogued as rs769310192, COSV56361328; called by muse, mutect2, varscan2
- DUSP6 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV54378306; called by muse, mutect2, varscan2
- DYNC2H1 | c.7869G>T p.Q2623H | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV62093572; called by muse, mutect2, varscan2
- DYNC2LI1 | c.522T>G p.I174M | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as COSV53184043; called by muse, varscan2
- DYNC2LI1 | c.634T>C p.Y212H | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV53184053; called by muse, mutect2, varscan2
- DYTN | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65970739; called by muse, mutect2, varscan2
- ECD | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 22/160 reads (14%) | catalogued as COSV65900333; called by muse, mutect2, varscan2
- ECT2L | c.2040G>T p.M680I | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV62885467; called by muse, mutect2, varscan2
- EEF1A1 | c.1133A>C p.K378T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV58550050; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1911A>C p.E637D | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV62568661; called by muse, mutect2, varscan2
- EFCAB12 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58177126; called by muse, mutect2, varscan2
- EFCAB13 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV58949882; called by muse, mutect2, varscan2
- EFCAB5 | c.416T>G p.L139R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV57932319; called by muse, mutect2, varscan2
- EFCAB6 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as rs140051719; called by muse, mutect2, varscan2
- EFHB | c.2219G>T p.R740I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV55549696; called by muse, mutect2, varscan2
- EFHC2 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746108363, COSV69554240; called by muse, mutect2, varscan2
- EIF2S2 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66620980; called by muse, mutect2
- EIF3J | c.208A>C p.K70Q | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as COSV56009112; called by muse, mutect2, varscan2
- EIF4G3 | c.4189C>A p.L1397I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV99943948; called by muse, mutect2
- ELF3 | c.916del p.L306Cfs*19 | Frame Shift Del (DEL) | VAF 87/333 reads (26%) | catalogued as COSV62838397; called by mutect2, varscan2
- ELF4 | c.1741A>G p.T581A | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57453320; called by muse, mutect2, varscan2
- ELF5 | c.541G>A p.D181N (on ENST00000312319 / NM_198381.2; = p.D171N on NM_001422.4) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56629290; called by muse, mutect2, varscan2
- ELL2 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs983451634, COSV52983466; called by muse, mutect2, varscan2
- ELL2 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 26/420 reads (6%) | catalogued as rs1416098476, COSV52981190; called by muse, mutect2
- ELL3 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 64/292 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs769387331, COSV55857066, COSV55857265; called by muse, mutect2, varscan2
- ELOA2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 31/399 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs765481551, COSV55300627; called by muse, mutect2
- ELOVL4 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63954165; called by muse, mutect2, varscan2
- EMILIN2 | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as rs777324557; called by mutect2, varscan2
- EMX1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777186799, COSV50689363; called by muse, mutect2, varscan2
- ENAM | c.1454T>G p.F485C | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV68536318; called by muse, mutect2, varscan2
- ENDOD1 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.212); catalogued as rs200901212, COSV53589997, COSV99566557; called by muse, mutect2, varscan2
- ENOX2 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs1180506827, COSV100584545; called by muse, mutect2
- EPB41L4A | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.559); catalogued as rs772237814, COSV54863025; called by muse, mutect2, varscan2
- EPB41L4A | c.33T>G p.F11L | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV54873349; called by muse, mutect2, varscan2
- EPG5 | c.5682A>G p.I1894M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.668); catalogued as rs372631564; called by mutect2, varscan2
- EPHA3 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV60712551; called by muse, mutect2, varscan2
- EPHA7 | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65169707, COSV65170837; called by muse, mutect2
- EPHB1 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.137); catalogued as COSV67664254; called by muse, varscan2
- EPHX4 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64889663; called by muse, mutect2, varscan2
- EPS15 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 106/399 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs777135649, COSV65531582; called by muse, mutect2, varscan2
- EPS8L3 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs935252097; called by muse, mutect2
- ERBB4 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99618974; called by muse, mutect2
- ERBIN | c.1925C>A p.S642Y | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52312995, COSV52329064; called by muse, mutect2, varscan2
- ERCC6L | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339227994, COSV57819781; called by muse, mutect2, varscan2
- ERCC6L2 | c.504A>C p.K168N | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56631896; called by muse, mutect2
- ERICH3 | c.2923C>A p.L975I | Missense Mutation (SNP) | VAF 105/404 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV58610538; called by muse, mutect2, varscan2
- ERICH3 | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV58610549; called by muse, mutect2, varscan2
- ERICH3 | c.316-1G>T p.X106_splice | Splice Site (SNP) | VAF 43/222 reads (19%) | catalogued as COSV100443777, COSV58602622; called by muse, mutect2, varscan2
- ERMARD | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as rs537314791; called by muse, mutect2
- ERN2 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV56834993; called by muse, mutect2, varscan2
- ESCO1 | c.1023G>T p.L341F | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV52520599; called by muse, mutect2, varscan2
- ESF1 | c.1904T>C p.F635S | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52522151; called by muse, mutect2, varscan2
- ESF1 | c.562T>G p.L188V | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52522162; called by muse, mutect2, varscan2
- ESRRG | c.1078A>G p.K360E | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.22); catalogued as COSV63167259; called by muse, mutect2, varscan2
- ESX1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65423892; called by muse, mutect2, varscan2
- ETAA1 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as COSV55473813; called by muse, mutect2, varscan2
- ETF1 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV62127645; called by muse, varscan2
- ETF1 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62127652; called by muse, mutect2, varscan2
- ETS1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV60094615; called by muse, mutect2
- EVA1A | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs761924250, COSV52059603; called by muse, mutect2, varscan2
- EVI2B | c.1248T>G p.D416E | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV58364356; called by muse, mutect2, varscan2
- EVI2B | c.600T>G p.Y200* | Nonsense Mutation (SNP) | VAF 151/982 reads (15%) | catalogued as COSV58364367; called by muse, mutect2, varscan2
- EVX2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 27/125 reads (22%) | catalogued as COSV57963938; called by muse, mutect2, varscan2
- EXPH5 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs780333058, COSV56203534; called by muse, mutect2, varscan2
- F2RL2 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56971084; called by muse, mutect2, varscan2
- F5 | c.2448G>T p.K816N | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV63125430; called by muse, mutect2, varscan2
- F5 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as CM950384, COSV63125434; called by muse, mutect2, varscan2
- F5 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV63120327; called by muse, varscan2
- FABP7 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs903265251, COSV62956573; called by muse, mutect2, varscan2
- FAM122B | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 76/421 reads (18%) | catalogued as COSV53231578; called by muse, mutect2, varscan2
- FAM122C | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 24/574 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV66194818; called by muse, mutect2
- FAM135A | c.254A>G p.D85G (on ENST00000370479 / NM_001351599.1; = p.D42G on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52053925; called by muse, mutect2, varscan2
- FAM135B | c.3131T>G p.F1044C | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52734565, COSV52750348; called by muse, mutect2
- FAM13A | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1474941643, COSV52005645; called by muse, mutect2, varscan2
- FAM13B | c.2110C>A p.H704N | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV50368118; called by muse, mutect2, varscan2
- FAM169A | c.51A>C p.E17D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65846776; called by muse, mutect2, varscan2
- FAM170A | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100088841; called by muse, mutect2, varscan2
- FAM184A | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 45/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100137538; called by muse, mutect2
- FAM184A | c.2106G>T p.Q702H | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58855786; called by muse, mutect2, varscan2
- FAM184A | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 31/206 reads (15%) | catalogued as COSV58855793; called by muse, mutect2, varscan2
- FAM184A | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV58855802; called by muse, varscan2
- FAM209B | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100990936; called by muse, mutect2
- FAM217B | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs200508394, COSV62564615; called by muse, mutect2, varscan2
- FAM227B | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV54813544; called by muse, mutect2, varscan2
- FAM227B | c.71A>C p.K24T | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as COSV54813553; called by muse, mutect2, varscan2
- FAM237A | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69305139; called by muse, mutect2, varscan2
- FAM47A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 86/420 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs1426442027, COSV60494190; called by muse, mutect2, varscan2
- FAM81A | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 27/221 reads (12%) | catalogued as rs1353344073, COSV55677330; called by muse, mutect2, varscan2
- FAM9B | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 48/316 reads (15%) | catalogued as COSV59119752; called by muse, mutect2, varscan2
- FAN1 | c.2090G>T p.R697I | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs749900780, COSV62951391; called by muse, mutect2, varscan2
- FANCD2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as rs1004943548, COSV55040760; called by muse, mutect2, varscan2
- FANCM | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | catalogued as COSV57502713; called by muse, mutect2, varscan2
- FANCM | c.2381T>G p.F794C | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.408); catalogued as COSV57502721; called by muse, mutect2
- FANK1 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 30/178 reads (17%) | catalogued as COSV64156739; called by muse, mutect2, varscan2
- FARP1 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs190467958; called by muse, mutect2, varscan2
- FASTKD1 | c.1584G>T p.M528I | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV71624405; called by muse, mutect2, varscan2
- FASTKD3 | c.1367C>A p.S456* | Nonsense Mutation (SNP) | VAF 38/192 reads (20%) | catalogued as COSV52942579, COSV52944869; called by muse, mutect2, varscan2
- FAT3 | c.12661G>A p.V4221I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749339528, COSV53082658; called by muse, mutect2, varscan2
- FAT4 | c.14369C>A p.S4790Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs544699967, COSV58674674; called by mutect2, varscan2
- FAT4 | c.14852A>C p.D4951A | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58692774; called by muse, mutect2, varscan2
- FAU | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV54195311; called by mutect2, varscan2
- FBN1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1060501079, COSV57321058; called by muse, mutect2, varscan2
- FBXO11 | c.2550C>A p.F850L (on ENST00000403359 / NM_001190274.2; = p.F766L on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52282096; called by muse, mutect2, varscan2
- FBXO21 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57973638; called by muse, mutect2, varscan2
- FBXO34 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775419301, COSV58254251; called by muse, varscan2
- FBXO47 | c.166T>G p.L56V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65242078; called by muse, mutect2, varscan2
- FBXO6 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.189); catalogued as rs1258160159, COSV65100862; called by muse, mutect2, varscan2
- FBXW11 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); catalogued as COSV51610769; called by muse, mutect2
- FBXW2 | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.38); catalogued as COSV61597350; called by muse, mutect2, varscan2
- FCGR3A | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749283416, COSV63459889; called by muse, varscan2
- FCHSD1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs558644593, COSV51837764; called by muse, mutect2, varscan2
- FCRL2 | c.1518G>T p.K506N | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63834068, COSV63834087; called by muse, mutect2, varscan2
- FCRL5 | c.2079T>G p.F693L | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62516280; called by muse, mutect2, varscan2
- FER1L6 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs753364876, COSV67549608; called by mutect2, varscan2
- FER1L6 | c.5037C>A p.F1679L | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV67548944; called by muse, mutect2, varscan2
- FGD1 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64309022; called by muse, mutect2, varscan2
- FGD6 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377183623; called by muse, mutect2, varscan2
- FGL1 | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67712153; called by muse, varscan2
- FIGNL1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866389991, COSV63553701; called by muse, mutect2, varscan2
- FKBP7 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs376048035; called by muse, varscan2
- FKBP7 | c.21C>A p.F7L | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51845985, COSV51846743; called by muse, varscan2
- FLRT2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58144608; called by muse, mutect2
- FLT3 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV54057630; called by muse, mutect2
- FLVCR2 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV53163037; called by muse, mutect2, varscan2
- FMN1 | c.4121C>A p.S1374Y (on ENST00000616417 / NM_001277313.2; = p.S1151Y on NM_001103184.4) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.825); catalogued as COSV57925879; called by muse, mutect2, varscan2
- FMN1 | c.2617G>A p.A873T (on ENST00000616417 / NM_001277313.2; = p.A650T on NM_001103184.4) | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.552); catalogued as rs372119445; called by muse, mutect2, varscan2
- FNIP2 | c.3196A>C p.S1066R | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52441570; called by muse, mutect2, varscan2
- FOCAD | c.348A>C p.E116D | Missense Mutation (SNP) | VAF 124/518 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.376); catalogued as COSV58097397, COSV58102164; called by muse, mutect2, varscan2
- FOXI1 | c.272T>G p.V91G | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV60389003; called by muse, mutect2
- FOXN2 | c.414T>G p.I138M | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61318748; called by muse, mutect2
- FOXN4 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs373055287; called by muse, mutect2, varscan2
- FOXP2 | c.1481A>G p.N494S | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1300216902, COSV100646387; called by muse, mutect2
- FPGT-TNNI3K | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200196531, COSV58558224; called by muse, mutect2, varscan2
- FPR3 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100200602; called by muse, mutect2, varscan2
- FREM1 | c.2133G>T p.K711N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66525399; called by muse, mutect2, varscan2
- FREM1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV66519862; called by muse, mutect2, varscan2
- FREM2 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs201675703, COSV54842189; called by muse, mutect2, varscan2
- FRK | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs753596132, COSV73384053; called by muse, mutect2, varscan2
- FRMD7 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV53746529; called by muse, mutect2, varscan2
- FRMPD1 | c.1133C>A p.S378Y | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV66700930; called by muse, mutect2, varscan2
- FRMPD4 | c.1068C>T p.I356= | Splice Region (SNP) | VAF 21/138 reads (15%) | catalogued as rs1040001720, COSV66217578; called by muse, mutect2, varscan2
- FRRS1 | c.859-2A>G p.X287_splice | Splice Site (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99789760; called by muse, mutect2, varscan2
- FRS2 | c.359G>T p.R120I | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54725407; called by muse, mutect2, varscan2
- FRY | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 37/239 reads (15%) | catalogued as COSV100969939, COSV66572854, COSV66580479; called by muse, mutect2, varscan2
- FRYL | c.3428C>A p.S1143Y | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV99976317; called by muse, mutect2
- FSHB | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV54222310; called by muse, mutect2, varscan2
- FSIP1 | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV63225467; called by muse, mutect2, varscan2
- FSTL4 | c.706C>A p.R236S | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV54770553, COSV54775580; called by muse, mutect2, varscan2
- FTSJ3 | c.630C>A p.F210L | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as rs1456609717, COSV59562935; called by muse, mutect2, varscan2
- FUNDC2 | c.540del p.F180Lfs*52 | Frame Shift Del (DEL) | VAF 28/188 reads (15%) | catalogued as COSV65670657; called by pindel, varscan2
- FUT8 | c.1033G>T p.E345* (on ENST00000360689 / NM_001371534.1; = p.E182* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV61282406, COSV61286786; called by muse, mutect2, varscan2
- FXR1 | c.380T>C p.F127S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV99976250; called by muse, mutect2, varscan2
- FYB1 | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 81/413 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60943808, COSV60951390; called by muse, mutect2, varscan2
- FYCO1 | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99945347; called by muse, mutect2, varscan2
- FZD3 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 46/590 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs757928052, COSV99527981; called by muse, mutect2
- GABRA3 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.086); catalogued as rs868315790, COSV100942422; called by muse, mutect2
- GABRB3 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as rs766672883, COSV100158514, COSV54670778; called by muse, mutect2, varscan2
- GABRP | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as COSV54663737; called by muse, mutect2, varscan2
- GABRQ | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1357029655, COSV100941144; called by muse, mutect2
- GALNTL5 | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.501); catalogued as COSV67180466; called by muse, mutect2, varscan2
- GALNTL6 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV72491706; called by muse, mutect2, varscan2
- GAN | c.1528T>G p.L510V | Missense Mutation (SNP) | VAF 24/502 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101634031; called by muse, mutect2
- GAS2L2 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 120/418 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs139833672; called by muse, mutect2, varscan2
- GBP7 | c.1690T>G p.F564V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV54010336; called by muse, mutect2, varscan2
- GCC1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50001350; called by muse, mutect2, varscan2
- GCC1 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV50001353; called by muse, mutect2, varscan2
- GCG | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100972727, COSV64961667, COSV99072052; called by muse, mutect2, varscan2
- GDF9 | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as COSV51526662; called by muse, mutect2, varscan2
- GDPD2 | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV65533386; called by muse, varscan2
- GEN1 | c.1833A>C p.K611N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as COSV58057262; called by muse, mutect2, varscan2
- GFM2 | c.63+2T>C p.X21_splice | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99713617; called by muse, mutect2, varscan2
- GFRA1 | c.1304C>A p.S435* | Nonsense Mutation (SNP) | VAF 62/366 reads (17%) | catalogued as rs76681527, COSV62605617, COSV62607591; called by muse, mutect2, varscan2
- GFRA2 | c.1072G>A p.G358S | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs754491537; called by muse, mutect2, varscan2
- GGCT | c.145T>G p.F49V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV50040920; called by muse, varscan2
- GIGYF2 | c.2834C>A p.S945* | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | catalogued as COSV65250901; called by muse, mutect2, varscan2
- GIMAP4 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 65/268 reads (24%) | catalogued as COSV55431809, COSV55433315; called by muse, mutect2, varscan2
- GIMAP6 | c.39T>G p.N13K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV100188140; called by muse, varscan2
- GIPR | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1405223050; called by muse, mutect2, varscan2
- GJA8 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.109); catalogued as rs377069862, COSV53790632; called by muse, mutect2, varscan2
- GJC3 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 79/523 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs191464858, COSV57210508; called by muse, mutect2, varscan2
- GK5 | c.153A>C p.E51D | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV67486051; called by muse, varscan2
- GLA | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 53/860 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV54508864; called by muse, mutect2
- GLB1L3 | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 63/740 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV66282210; called by muse, mutect2
- GLDN | c.838A>C p.N280H | Missense Mutation (SNP) | VAF 57/353 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59090919; called by muse, mutect2, varscan2
- GLI3 | c.4329C>A p.F1443L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV67890425; called by muse, mutect2, varscan2
- GLP1R | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.619); catalogued as COSV100952470; called by muse, mutect2, varscan2
- GLP1R | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs199796313, COSV64714509, COSV64715892; called by muse, mutect2, varscan2
- GLRA3 | c.1360C>A p.L454I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as COSV56857597; called by muse, mutect2, varscan2
- GLUL | c.1078C>A p.L360I | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV59382585; called by muse, mutect2, varscan2
- GNRH1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs773272755, COSV52382359; called by muse, mutect2, varscan2
- GOLGA6L22 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs560556412; called by muse, mutect2, varscan2
- GORASP1 | c.1323A>C p.*441Yext*5 | Nonstop Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV56532678; called by muse, varscan2
- GPAT3 | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV52357899; called by muse, mutect2, varscan2
- GPATCH1 | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 33/154 reads (21%) | catalogued as rs956239069, COSV50114667; called by muse, mutect2, varscan2
- GPC3 | c.1430C>A p.S477Y | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63661139, COSV63666673; called by muse, varscan2
- GPM6A | c.540T>A p.F180L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV54548420; called by muse, varscan2
- GPR101 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs781313990, COSV53239350; called by muse, mutect2, varscan2
- GPR148 | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1410609021, COSV59308642; called by muse, mutect2, varscan2
- GPR156 | c.2262C>A p.F754L | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs368406321, COSV59939704; called by muse, mutect2, varscan2
- GPR158 | c.1149A>T p.K383N | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV66273832; called by muse, mutect2, varscan2
- GPR161 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs199866265, COSV54788031; called by muse, mutect2, varscan2
- GPR31 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs770257391; called by mutect2, varscan2
- GPR87 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 31/166 reads (19%) | catalogued as rs1244447711, COSV53462939; called by muse, mutect2, varscan2
- GPRASP1 | c.3924C>A p.F1308L | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV64355922; called by muse, mutect2, varscan2
- GPS2 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 30/125 reads (24%) | catalogued as COSV59747647; called by muse, mutect2, varscan2
- GPX6 | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62657952; called by muse, mutect2
2,052 further variants in this file (1,551 protein-altering or splice-affecting, 438 silent, 63 other) are not listed here.
